Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A03N, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A03N-01B (Primary Tumor).

[page 1 of 6]
....

Clinical Diagnosis & History:

y/o female with left breast ductal CA.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, left axilla (fs)
- 2: SP: Sentinel node #2, level 1, left axilla (fs)
- 3: SP: Sentinel node #3, level 1, left axilla (fs)
- 4: SP: Sentinel node #4, level 1, left axilla (fs)
- 5: SP: Left breast
- 6: SP: Sentinel node #5, level 1, left axilla
- 7: SP: Left axillary contents, levels 1 and 2
- 8: SP: Left subscapular nodes

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1, LEVEL I, LEFT AXILLA; EXCISION:
- METASTATIC CARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE (1/1).
- THE METASTATIC FOCUS MEASURES 2 MM.
- NO EXTRANODAL EXTENSION IS SEEN.
- 2) LYMPH NODE, SENTINEL #2, LEVEL I, LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODE, SENTINEL #3, LEVEL I, LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE, SENTINEL #4, LEVEL I, LEFT AXILLA; EXCISION:
- METASTATIC CARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE IN THE FORM OF A SINGLE CLUSTER IDENTIFIED IN A H/E STAINED SECTION (1/1).
- 5) BREAST, LEFT; MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 2.5 CM IN LARGEST DIMENSION GROSSLY (AT LEAST 2.3 CM MICROSCOPICALLY).
- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID AND CRIBRIFORM TYPES WITH INTERMEDIATE NUCLEAR GRADE AND MINIMAL NECROSIS.
- THE DCIS CONSTITUTES <= 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH THE INVASIVE COMPONENT.
- FOCAL LOBULAR CARCINOMA IN SITU (LCIS) IS ALSO IDENTIFIED, CLASSICAL TYPE

** Continued on next page **

1CD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9

lw
10/21/11

Case It (circle):	DISQUALIFIED	
	10/21/11	

[page 2 of 6]
(TYPE A).

- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT AND UPPER INNER QUADRANT.
- THE DCIS IS LOCATED IN THE UPPER OUTER QUADRANT AND UPPER INNER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA IS IDENTIFIED.

- CALCIFICATIONS ARE PRESENT IN THE IN SITU CARCINOMA AND IN BENIGN BREAST PARENCHYMA.

- VASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.

- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.

- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES AND INTRADUCTAL PAPILLOMA WITH ATYPIA.

- RESULTS OF SPECIAL STUDIES (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

- 6) LYMPH NODES, SENTINEL #5, LEVEL I, LEFT AXILLA; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

- 7) LYMPH NODES, LEFT AXILLA, LEVEL I AND II; EXCISION:
- LEVEL I: ELEVEN BENIGN LYMPH NODES (0/11).
- LEVEL II: ONE BENIGN LYMPH NODE (0/1).

- 8) LYMPH NODE, LEFT SUBCAPSULAR; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	ER-C	
	PR-C	
	HER2-C	
	NEG-HER2	
	NEG CONT	
	IMM RECUT	

Gross Description:

M.D.

M.D.

- 1). The specimen is received fresh for frozen section consultation, labeled "sentinel node number 1, level 1 left axilla" and consists of one lymph node measuring 2.5 x 1.2 x 1.0 cm. Entirely submitted for frozen section (bisected).

** Continued on next page **

[page 3 of 6]
Summary of sections:
FSA-FSB -- frozen section control

M.D.

2). The specimen is received fresh for frozen section consultation, labeled "sentinel node number 2, level 1 left axilla" and consists of one lymph node measuring 1.2 x 0.5 x 0.5 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

M.D.

3). The specimen is received fresh for frozen section consultation, labeled "sentinel node number 3, level 1 left axilla" and consists of one lymph node measuring 1.2 x 0.5 x 0.5 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

M.D.

4). The specimen is received fresh for frozen section consultation, labeled "Sentinel node number four, level one, left axilla" and consists of one lymph node measuring 0.9 x 0.4 x 0.4 cm. The lymph node is bisected and entirely submitted for frozen section diagnosis.

Summary sections:
FSC -- frozen section control

, M.D.

5) The specimen is received fresh, labeled "Left breast" and consists of a breast measuring 21.5 x 14.0 x 3.4 cm with an overlying skin ellipse measuring 10.8 x 5.0 cm. Situated centrally on the skin surface is an everted nipple measuring 1.3 x 1.3 x 0.6 cm and areola measuring 2.2 x 2.2 cm. A suture demarcates the axillary aspect. The posterior surface of the breast is inked black, the anterior aspect is blue and the axillary aspect green and the specimen is serially sectioned to reveal an indurated tan-white tumor measuring 2.5 x 2.4 x 2.3 cm, and located predominantly in the upper outer quadrant, between 12 o' clock and one o' clock, focally extending into the upper inner quadrant, 0.2 cm from the anterior aspect and 0.7 cm from the deep margin. Sectioning of the axillary aspect reveals no grossly identifiable lymph nodes. Tissue is submitted for TPS. Representative sections are submitted.

Summary of sections:
N - nipple

** Continued on next page **

[page 4 of 6]
NB - nipple base
T - tumor
TAM, TDM - tumor to anterior aspect and deep margin respectively
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant

P.A.

6). The specimen is received in formalin, labeled "Sentinel node, number five, level one, left axilla" and consists of two single pink-tan firm lymph nodes measuring 0.9 x 0.6 x 0.3 and 1.4 x 0.8 x 0.6 cm. The lymph nodes are bisected and entirely submitted.

Summary of sections:
BLN bisected lymph nodes

P.A.

7). The specimen is received in formalin, labeled "Left axillary contents one and two tags attached". It consists of a 7 x 4 x 3 cm fragment of fibroadipose tissue. Two tags are present, designating levels 1 and 2. Multiple lymph nodes are identified, ranging in size from 0.9 cm to 2.7 cm. All identified lymph nodes are submitted.

Summary of sections:
L1LN - level one lymph nodes
L1BLN - level one bisected lymph nodes
L2BLN - level two bisected lymph nodes

P.A.

8). The specimen is received in formalin, labeled "Left sub-scapular node" and consists of a single pink-tan, fatty lymph node measuring 0.3 x 0.2 x 0.2 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

Summary of Sections:

** Continued on next page **

[page 5 of 6]
Part 1: SP: Sentinel node #1, level 1, left axilla (fs)

Block	Sect.	Site	PCs
1		fsa	1
1		fsb	1

Part 2: SP: Sentinel node #2, level 1, left axilla (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Sentinel node #3, level 1, left axilla (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 4: SP: Sentinel node #4, level 1, left axilla (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 5: SP: Left breast

Block	Sect.	Site	PCs
2		liq	2
2		loq	2
1		n	1
1		nb	1
4		t	4
1		tam	1
1		tdm	1
2		uiq	2
2		uoq	2

Part 6: SP: Sentinel node #5, level 1, left axilla

Block	Sect.	Site	PCs
2		BLN	4

Part 7: SP: Left axillary contents, levels 1 and 2

Block	Sect.	Site	PCs
4		L1BLN	8
2		L1LN	4
1		L2BLN	2

Part 8: SP: Left subscapular nodes

Block	Sect.	Site	PCs
1		LN	1

Procedures/Addenda:
Addendum

** Continued on next page **

[page 6 of 6]
Date Ordered: Status: Signed Out
Date Complete: By: MD
Date Reported:

Addendum Diagnosis

ADDENDUM REPORT

SITE: LEFT BREAST (PART #5)
ER: 70% NUCLEAR STAINING WITH MODERATE TO STRONG INTENSITY
PR: 3% NUCLEAR STAINING WITH WEAK INTENSITY
HER2/NEU(HERCEPT): NEGATIVE (STAINING INTENSITY OF 0)

MD

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1A,B) FROZEN SECTION DIAGNOSIS: METASTATIC CARCINOMA.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES.
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES.
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODE.
PERMANENT DIAGNOSIS: SAME.

MD

** End of Report **

Source: NCI Genomic Data Commons file 68d88e7b-435c-49fe-b841-f955823c7c87 (TCGA-AO-A03N.44527CD3-6EC3-4861-8394-CEA005A17A9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).